Gene-level copy-number profile of tumor specimen ALCH-AF3G-TTP1-A from ALCHEMIST case ALCH-AF3G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 41.0 years (14,968 days).
Specimen ALCH-AF3G-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e9bc8dd8-29ce-4f20-adf0-7a216f4be655.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF3G-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/a1acf20c-3181-4f63-9964-5fbd087b1c0f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 563; copy number 2: 15,571; copy number 3: 1,455; copy number 4: 31,896; copy number 5: 3,535; copy number 6: 4,645; copy number 7: 264; copy number 8: 104; copy number 9: 89; copy number 10: 174; copy number 11: 2; copy number 12: 2; copy number 25: 2.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr9:75,198,071–75,198,177, 1 gene: RNU6-1228P.
- chr14:60,397,757–60,400,013, 2 genes (within-gene range 0–2): RBM8B, GNRHR2P1.
- chr16:32,649,193–32,678,831, 5 genes: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3.
- chr16:34,120,470–34,979,844, 10 genes: AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2, BCLAF1P2, AC135776.4, LINC02184.
- chr16:35,722,268–35,912,516, 26 genes: AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr22:17,352,881–17,353,177, 1 gene: RN7SL843P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 269 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:166,839,447–166,876,264, 2 genes, copy number 12 (within-gene range 5–12): POGK, TADA1.
- chr8:143,915,153–143,976,734, 2 genes, copy number 10: PLEC, MIR661.
- chr9:108,626,833–109,320,964, 15 genes, copy number 10 (within-gene range 5–10): AL669983.1, AL358779.1, RPL36AP35, AL359692.1, ACTL7B, ACTL7A, ELP1, ABITRAM, CTNNAL1, TMEM245, Y_RNA, MIR32, FRRS1L, EPB41L4B, RNU6-984P.
- chr9:109,375,466–114,696,315, 98 genes, copy number 10 (broad region; genes not listed).
- chr9:114,845,594–116,402,321, 14 genes, copy number 10: AL133412.1, DELEC1, TNFSF8, TNC, AL162425.1, AL355601.1, AL691420.1, U2, LINC00474, AL691426.1, PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1.
- chr9:121,567,057–122,093,606, 5 genes, copy number 9: DAB2IP, AL357936.1, AL596244.1, TTLL11, TTLL11-IT1.
- chr9:122,908,056–123,268,586, 12 genes, copy number 9–10: ZBTB6, ZBTB26, AC007066.2, AC007066.3, RABGAP1, RNY1P15, AC007066.1, GPR21, AL365338.1, MIR600HG, STRBP, MIR600.
- chr9:123,379,654–123,930,152, 1 gene, copy number 9 (within-gene range 6–9): DENND1A.
- chr9:123,736,437–124,772,927, 21 genes, copy number 9: AL390774.2, AL390774.1, PIGFP2, LHX2, AC006450.3, AC006450.1, AC006450.2, NEK6, AL162724.2, AL162724.1, PSMB7, ADGRD2, NR5A1, AL354979.1, NR6A1, AL669818.1, RN7SL302P, MIR181A2HG, MIR181A2, MIR181B2, AL354928.1.
- chr12:65,134,688–65,135,273, 1 gene, copy number 9: APOOP3.
- chr12:66,116,555–67,590,771, 23 genes, copy number 9 (within-gene range 4–9): LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408.
- chr12:68,248,242–68,745,809, 17 genes, copy number 9: IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39.
- chr12:69,901,918–72,670,758, 38 genes, copy number 10 (within-gene range 6–10): PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2.
- chr12:73,820,315–74,402,600, 1 gene, copy number 9 (within-gene range 3–9): LINC02882.
- chr12:74,248,637–75,390,928, 15 genes, copy number 9–10 (within-gene range 6–10): AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2.
- chr16:32,356,981–32,380,049, 2 genes, copy number 11: AC133548.1, ACTR3BP3.
- chr16:35,040,164–35,085,060, 2 genes, copy number 25 (within-gene range 0–25): CCNYL3, CLUHP11.

Autosomal genes at a single copy (total copy number 1): 52. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
